Somatic mutation profile of tumor specimen MP2PRT-PATIHF-TBP1-A (aliquot MP2PRT-PATIHF-TBP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PATIHF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.2 years (2,985 days).
Specimen MP2PRT-PATIHF-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 361a250c-3d84-4d82-9c2c-aef4f4f7f189.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIHF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIHF-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02661e00-f0b7-4dce-a2da-3d41b3747de7

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Ins 1, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACY3 | c.380T>A p.I127N | Missense Mutation (SNP) | VAF 194/464 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99663123; called by muse, varscan2
- FAM83H | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 88/832 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs782518606, COSV101186963; called by muse, varscan2
- PATE3 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs760066913; called by muse, mutect2
- PI4KB | c.2114C>T p.T705M (on ENST00000368873 / NM_001369623.1; = p.T717M on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/514 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1276735332; called by muse, mutect2
- PRDM13 | c.1244delinsAAGAA p.L415Qfs*38 | Frame Shift Ins (INS) | VAF 270/827 reads (33%) | called by pindel, varscan2*
- SDK1 | c.6366T>A p.D2122E | Missense Mutation (SNP) | VAF 124/284 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM79 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 33/701 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.103); called by muse, mutect2
- UBR2 | c.1544A>G p.Q515R | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- USH2A | c.12305T>A p.I4102N | Missense Mutation (SNP) | VAF 117/252 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, varscan2
- DEPDC7 | c.762C>G p.L254= (on ENST00000241051 / NM_001077242.2; = p.L245= on NM_139160.2) | Silent (SNP) | VAF 17/299 reads (6%) | catalogued as COSV53809180; called by muse, mutect2
- PCMTD1 | c.-399C>G | 5'UTR (SNP) | VAF 63/842 reads (7%) | called by muse, mutect2
